MMRF case MMRF_1772 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8e1dbe30-72d8-4008-91bd-e4eb88d11fea

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.8 years (17,827 days); Days to last known disease status: 1,157 days (3.2 years); Days to last follow up: 1,157 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 73 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 210 days; Days to treatment end: 210 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1101 mg/dL; Immunoglobulin G 82.2 g/L; Immunoglobulin A 0.012 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 4.22 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 26 g/L; Total Protein 11 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 5.26 mg/dL.
- Day 80 (ECOG 1): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1430 mg/dL; Immunoglobulin G 51.5 g/L; Immunoglobulin A 0.015 g/L; Lactate Dehydrogenase 1.23 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 6.72 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 1.8 mmol/L; Albumin 22 g/L; Total Protein 8.7 g/dL; Glucose 6.44 mmol/L.
- Day 170: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Immunoglobulin G 8.54 g/L; Hemoglobin 8 mmol/L; Leukocytes 81 ×10⁹/L; Absolute Neutrophil 6.54 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 275 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 8.36 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.16 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 359 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 8.56 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.86 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.23 mmol/L.
- Day 429 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 7.35 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Total Protein 6.1 g/dL; Glucose 5.83 mmol/L.
- Day 533 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 6.95 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.78 mmol/L.
- Day 625: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 7.32 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.27 mmol/L.
- Day 709 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 8.47 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.79 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 807 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 8.3 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.17 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 891 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 9.36 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.42 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 975 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 9.12 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.88 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.89 mmol/L.
- Day 1,059: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.47 mg/dL; Immunoglobulin G 9.95 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.17 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 1,157: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 10.5 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.23 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -13: Weight: 81 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1772_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1772_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
- Sample MMRF_1772_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
